Somatic mutation profile of tumor specimen 09659708-7747-4d59-a3b9-e221e0 (aliquot 09659708-7747-4d59-a3b9-e221e0_D6) from CPTAC case 01BR017, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 45.0 years (16,424 days).
Specimen 09659708-7747-4d59-a3b9-e221e0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed15ee8f-ed08-4447-ace2-d3d31df2fcd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b76c68fc-2403-4e79-ad46-4ae336 (Blood Derived Normal), aliquot b76c68fc-2403-4e79-ad46-4ae336_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/952f4277-6142-48f2-bc1c-e9bbc5bae984

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Intron 3, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.11615G>C p.R3872T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV70199421; called by muse, mutect2
- CHD4 | c.5654G>A p.R1885H (on ENST00000357008 / NM_001363606.2; = p.R1895H on NM_001273.5) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769701672; called by muse, mutect2, varscan2
- CILP2 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs147931006, COSV52274817; called by muse, mutect2
- CKAP2L | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1023685641; called by muse, mutect2
- NLRC4 | c.263-1G>C p.X88_splice | Splice Site (SNP) | VAF 12/80 reads (15%) | catalogued as COSV61591900; called by muse, mutect2, varscan2
- SCAF1 | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs764558509; called by muse, mutect2, varscan2
- BSN | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- ETV6 | c.1155C>A p.N385K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2
- NUDT8 | c.195T>C p.S65= | Splice Region (SNP) | VAF 26/94 reads (28%) | called by mutect2, varscan2
- PKP3 | c.1530C>G p.I510M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by mutect2, varscan2
- SZT2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- OR2W1 | c.189C>T p.L63= | Silent (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- SEPTIN14 | c.915T>C p.Y305= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- STK39 | c.1446A>T p.V482= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV63594927; called by muse, mutect2
- TRAV34 | c.75G>A p.E25= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1395200324; called by mutect2, varscan2
- TTN | c.27165C>G p.S9055= (on ENST00000591111; = p.S8128= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- ANKS1A | c.3303+372C>T | Intron (SNP) | VAF 26/184 reads (14%) | called by mutect2, varscan2
- CORO1B | c.*769G>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs764213205; called by muse, mutect2, varscan2
- GIPC1 | c.656-23C>A | Intron (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2
- LINC01551 | n.1254+18631C>A | Intron (SNP) | VAF 17/163 reads (10%) | called by mutect2, varscan2
